Somatic mutation profile of tumor specimen TARGET-20-PATABB-09A (aliquot TARGET-20-PATABB-09A-01D) from TARGET case TARGET-20-PATABB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (652 days).
Specimen TARGET-20-PATABB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60cfac31-8951-44dd-8cbd-62129ecd00ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATABB-14A (Bone Marrow Normal), aliquot TARGET-20-PATABB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfda8ab0-52b6-4508-baff-1081867d02e3

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 50/292 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 45/518 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- DOC2B | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 88/1102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480171369; called by muse, mutect2
- KARS1 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs867340865, COSV56691747; called by muse, mutect2
- SLC5A7 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 130/609 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs779794468; called by muse, mutect2, varscan2
- SYT1 | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV54060755, COSV54066530; called by muse, mutect2
- ATG4A | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2
- B3GNT7 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- TSPOAP1 | c.5069A>G p.E1690G | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- GJB7 | c.636A>G p.Q212= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- NACC2 | c.1302C>T p.N434= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as rs144153703; called by mutect2, varscan2
- NAT8L | c.705C>T p.F235= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs752594380, COSV59051635; called by muse, mutect2, varscan2
- SV2B | c.402C>A p.P134= | Silent (SNP) | VAF 67/251 reads (27%) | catalogued as COSV100370572; called by muse, mutect2, varscan2
- TSR1 | c.18C>T p.P6= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs1445960787; called by muse, mutect2, varscan2
